Somatic mutation profile of tumor specimen TCGA-44-2662-01A (aliquot TCGA-44-2662-01A-01D-A271-08) from TCGA case TCGA-44-2662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-44-2662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72328e19-ca06-4df3-801f-814287b3eb9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2662-10A (Blood Derived Normal), aliquot TCGA-44-2662-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83ea44c2-1dca-4cec-9684-46435070405f

The open-access MAF lists 222 somatic variants for this specimen: 164 protein-altering or splice-affecting, 56 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 56, Nonsense Mutation 7, Splice Site 4, Splice Region 3, Frame Shift Del 3, Nonstop Mutation 2, RNA 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.882C>T p.L294= | Splice Region (SNP) | VAF 21/91 reads (23%) | catalogued as rs63751707, CS086119, COSV51615064; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.340A>T p.N114Y | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV55951076; called by muse, mutect2, varscan2
- ABCA13 | c.9493G>C p.D3165H | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71284199; called by muse, mutect2
- ABCA13 | c.14104G>A p.E4702K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV68944021; called by muse, mutect2
- ACTN2 | c.1347C>G p.S449R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100857132, COSV63972620; called by muse, mutect2, varscan2
- AMN | c.163-1G>A p.X55_splice | Splice Site (SNP) | VAF 64/212 reads (30%) | catalogued as COSV54486203; called by muse, mutect2, varscan2
- ANAPC1 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV61974574; called by muse, mutect2, varscan2
- AP4B1 | c.1775C>A p.S592* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV56723643, COSV56724960; called by muse, mutect2, varscan2
- ATP11C | c.2737A>T p.M913L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59560166; called by muse, mutect2, varscan2
- BAX | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV53169282; called by muse, mutect2, varscan2
- BCAS3 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs771698366, COSV66770605; called by muse, mutect2, varscan2
- BCHE | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52254138; called by muse, mutect2, varscan2
- BMERB1 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV55506397; called by muse, mutect2
- C1orf87 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV64596255; called by muse, mutect2, varscan2
- C2orf78 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.127); catalogued as rs1409069598, COSV68516575; called by muse, mutect2, varscan2
- CACNA1B | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV53116343; called by muse, mutect2, varscan2
- CACNA1E | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV62384201; called by muse, mutect2, varscan2
- CCDC146 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53544797; called by muse, mutect2, varscan2
- CCDC88A | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55057407; called by muse, mutect2, varscan2
- CCDC90B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52623501; called by muse, mutect2, varscan2
- CCP110 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66816618; called by muse, mutect2, varscan2
- CEP350 | c.5746G>A p.D1916N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1290923833, COSV62599414, COSV62610166; called by muse, mutect2
- CETN3 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV51616945; called by muse, mutect2, varscan2
- CHAMP1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs1555379780, COSV63521883; called by muse, mutect2, varscan2
- CHRNA4 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64718614; called by muse, mutect2, varscan2
- CNTLN | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52068519; called by muse, mutect2, varscan2
- COBL | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54339839; called by muse, mutect2, varscan2
- CPS1 | c.4502A>G p.*1501Wext*13 | Nonstop Mutation (SNP) | VAF 35/131 reads (27%) | catalogued as COSV51803674; called by muse, mutect2, varscan2
- CSMD3 | c.10640G>T p.S3547I (on ENST00000297405 / NM_001363185.1; = p.S3378I on NM_052900.3) | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV52116090; called by muse, mutect2
- CYFIP2 | c.2231G>T p.S744I (on ENST00000616178 / NM_001291722.2; = p.S719I on NM_014376.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59029806; called by muse, mutect2, varscan2
- DENND1B | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52461557; called by muse, mutect2, varscan2
- DKK2 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV53394673; called by muse, mutect2
- DNAH10 | c.4962C>G p.I1654M (on ENST00000409039; = p.I1593M on NM_207437.3) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV68989065, COSV68995673; called by muse, mutect2, varscan2
- DNAJC1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV65409444; called by muse, mutect2, varscan2
- DNAJC14 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54477846; called by muse, mutect2, varscan2
- EPAS1 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376653305; called by muse, mutect2, varscan2
- ERI3 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV64830371; called by muse, mutect2
- EXOC1 | c.838A>G p.M280V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV62119302; called by muse, mutect2, varscan2
- EXOG | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55062785; called by muse, mutect2, varscan2
- FASN | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350531560, COSV60749922; called by muse, mutect2
- FIZ1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs1471901175, COSV55607217, COSV99684747; called by muse, mutect2, varscan2
- FLCN | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 53/191 reads (28%) | catalogued as COSV53257576; called by muse, mutect2, varscan2
- FMN2 | c.4759T>G p.L1587V | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100144541, COSV60419697; called by muse, mutect2
- FRMD8 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs759320847, COSV53683382; called by muse, mutect2, varscan2
- FSIP2 | c.16905G>C p.K5635N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100554337; called by muse, mutect2
- GDAP2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV65611979; called by muse, mutect2, varscan2
- GOLGA4 | c.6639G>T p.L2213F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728697; called by muse, mutect2, varscan2
- GOLGA4 | c.6640G>T p.E2214* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100728700; called by muse, mutect2, varscan2
- GPATCH1 | c.1389G>T p.R463S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV50111020, COSV50111767, COSV50112587; called by muse, mutect2
- GPBP1L1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV51967299; called by muse, mutect2
- GSDMC | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs910419404, COSV52692967; called by muse, mutect2, varscan2
- GSDME | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV61651075; called by muse, mutect2, varscan2
- GTF2I | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs145729076; called by muse, mutect2
- HCN1 | c.1708A>T p.N570Y | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV57496403; called by muse, mutect2
- IL1RAPL1 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56234164, COSV56241733; called by muse, mutect2, varscan2
- IMPG2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV51974431; called by muse, mutect2, varscan2
- INTS11 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.378); catalogued as rs1246401538, COSV60087563; called by muse, mutect2, varscan2
- JAKMIP2 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54598719; called by muse, mutect2, varscan2
- KIN | c.479A>T p.K160M | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65430057; called by muse, mutect2, varscan2
- KLHDC4 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs867724471, COSV54507758; called by muse, mutect2
- KLHL15 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60139363; called by muse, mutect2, varscan2
- KLHL3 | c.1578C>A p.C526* | Nonsense Mutation (SNP) | VAF 41/209 reads (20%) | catalogued as COSV59051273, COSV59054767; called by muse, mutect2, varscan2
- KNDC1 | c.4697C>G p.S1566C | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757639617, COSV58832188, COSV58841310; called by muse, mutect2, varscan2
- KRTAP23-1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV61935551; called by muse, mutect2
- LCAT | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50452188; called by muse, mutect2
- LGALS9 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56348151; called by muse, mutect2, varscan2
- LGR4 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV60820240; called by muse, mutect2
- LINC02210-CRHR1 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.266); catalogued as COSV53275994, COSV53278487; called by muse, mutect2
- LRRC4C | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs775124868, COSV53419365; called by muse, mutect2, varscan2
- LYN | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV70205381; called by muse, mutect2, varscan2
- MACF1 | c.5555C>T p.S1852L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV57109524; called by muse, mutect2, varscan2
- MAIP1 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.741); catalogued as COSV54460280; called by muse, mutect2
- MANBA | c.1400T>A p.L467H (on ENST00000642252; = p.L421H on NM_005908.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56963278; called by muse, mutect2, varscan2
- MAP3K1 | c.4178C>G p.A1393G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV68122158; called by muse, mutect2
- MAP3K13 | c.1170-1G>A p.X390_splice | Splice Site (SNP) | VAF 10/77 reads (13%) | catalogued as COSV53984357; called by muse, varscan2
- MCTP1 | c.1515G>C p.K505N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV56505994; called by muse, mutect2, varscan2
- MGAT3 | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57864285; called by muse, mutect2
- MMRN1 | c.2906C>A p.P969Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV53338104, COSV99306646; called by muse, mutect2
- MMUT | c.532C>G p.P178A | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV51272443; called by muse, mutect2, varscan2
- MTBP | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59961276, COSV59961624; called by muse, mutect2
- MUC16 | c.18502G>C p.G6168R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV67449722, COSV67478144; called by muse, mutect2, varscan2
- MYCBP2 | c.4337G>C p.G1446A (on ENST00000357337; = p.G1484A on NM_015057.5) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62011668; called by muse, mutect2, varscan2
- MYLK2 | c.1409T>C p.V470A | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65658665; called by muse, mutect2, varscan2
- MYMK | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.482); catalogued as COSV60599989, COSV60600171; called by muse, mutect2, varscan2
- N4BP1 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV52209788; called by muse, mutect2
- NCKAP1L | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV53204058; called by muse, mutect2, varscan2
- NIPAL4 | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57423918, COSV57430406; called by muse, mutect2, varscan2
- NLRP13 | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100738131, COSV61620365; called by muse, mutect2, varscan2
- NOP16 | c.393G>A p.K131= | Splice Region (SNP) | VAF 13/108 reads (12%) | catalogued as COSV51257452; called by muse, mutect2, varscan2
- NPPA | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.049); catalogued as COSV56738360; called by muse, mutect2
- NUMB | c.981C>G p.I327M (on ENST00000355058; = p.I316M on NM_003744.5) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61828178, COSV61830428; called by muse, mutect2, varscan2
- OBSL1 | c.1776C>G p.I592M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV54712574; called by muse, mutect2, varscan2
- OLFM4 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54576084; called by muse, mutect2, varscan2
- OPLAH | c.3823C>T p.H1275Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66298192; called by muse, mutect2, varscan2
- OR10X1 | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV63767025; called by muse, mutect2, varscan2
- OR2L8 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61725780, COSV61728604; called by muse, mutect2, varscan2
- OR2M4 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV60707445; called by muse, mutect2, varscan2
- OR7A5 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59234224; called by muse, varscan2
- OR8G5 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV100422267; called by muse, mutect2
- PCDHA8 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs146582216, COSV65323904; called by muse, mutect2
- PDGFRB | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55801742; called by muse, mutect2, varscan2
- PHKB | c.2737G>C p.D913H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV54515846; called by muse, mutect2, varscan2
- PIGX | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56359154; called by muse, mutect2, varscan2
- PLCL1 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70822292; called by muse, mutect2
- PLD5 | c.1202C>A p.A401E (on ENST00000442594; = p.A339E on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV59135609; called by muse, mutect2, varscan2
- PLP1 | c.699C>T p.F233= | Splice Region (SNP) | VAF 18/54 reads (33%) | catalogued as COSV58275720; called by muse, mutect2, varscan2
- PPP2R2A | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60095931; called by muse, mutect2
- PPP6R3 | c.2493A>C p.K831N (on ENST00000393800 / NM_001352375.2; = p.K751N on NM_018312.5) | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV55722277; called by muse, mutect2, varscan2
- PREPL | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as COSV53215383; called by muse, mutect2, varscan2
- PTPRZ1 | c.5657C>G p.P1886R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV66431672; called by muse, mutect2, varscan2
- PURB | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770929116, COSV67480166; called by muse, mutect2, varscan2
- RASL11A | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99611009; called by muse, mutect2
- RIF1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV54613278; called by muse, mutect2, varscan2
- RPL11 | c.296C>T p.S99L (on ENST00000374550 / NM_001199802.1; = p.S100L on NM_000975.5) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs11556036, COSV65778420; called by muse, mutect2, varscan2
- RPL22 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52377101; called by muse, mutect2, varscan2
- RRAD | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV55341196; called by muse, mutect2, varscan2
- RUFY1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60158676; called by muse, mutect2, varscan2
- RYR1 | c.11362G>C p.E3788Q | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV62090965, COSV62091055; called by muse, mutect2
- SAMD15 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV53625454; called by muse, mutect2, varscan2
- SBSN | c.1463G>T p.G488V (on ENST00000452271 / NM_001166034.2; = p.G145V on NM_198538.4) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1408212094, COSV71733065; called by muse, mutect2, varscan2
- SEZ6L | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as COSV50658819; called by muse, mutect2, varscan2
- SLC12A7 | c.343-2A>T p.X115_splice | Splice Site (SNP) | VAF 21/234 reads (9%) | catalogued as COSV53754988; called by muse, mutect2
- SLC22A8 | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs755445118, COSV60324005; called by muse, mutect2, varscan2
- SLC39A12 | c.1793C>G p.S598C (on ENST00000377369 / NM_001145195.2; = p.S561C on NM_152725.3) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs765088632, COSV66195699; called by muse, mutect2, varscan2
- SLCO5A1 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV52654919; called by muse, mutect2, varscan2
- SMG5 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV62434193, COSV62434555; called by muse, mutect2, varscan2
- SP140 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV59446967; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.917G>C p.*306Sext*1 | Nonstop Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as rs1259641661, COSV60322588; called by muse, mutect2, varscan2
- STAG3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV57928012; called by muse, mutect2, varscan2
- STAT2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs149666262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAAR9 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71512183; called by muse, mutect2, varscan2
- TACC2 | c.6073G>C p.D2025H (on ENST00000334433; = p.D103H on NM_006997.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53277076, COSV53278918; called by muse, mutect2, varscan2
- THAP12 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as COSV52609641, COSV52611941; called by muse, mutect2, varscan2
- TLK2 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as rs777808122, COSV58297734; called by muse, mutect2, varscan2
- TMEM108 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV58865488; called by mutect2, varscan2
- TMPRSS11B | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100219268; called by muse, mutect2
- TRA2A | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51715959; called by muse, mutect2, varscan2
- TRBC2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs782153350; called by muse, mutect2, varscan2
- TRHDE | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53835267; called by muse, mutect2, varscan2
- TRPM7 | c.3053G>T p.R1018I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57914027; called by muse, mutect2, varscan2
- TSC22D2 | c.1610A>T p.Q537L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV62622252; called by muse, mutect2, varscan2
- TSHZ3 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.378); catalogued as COSV53665760; called by muse, mutect2
- TTC23 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV50440833; called by muse, mutect2, varscan2
- TTC8 | c.1374G>A p.M458I (on ENST00000338104 / NM_001288781.1; = p.M442I on NM_144596.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs758330370, COSV57626554; called by muse, varscan2
- TTN | c.11507A>T p.Q3836L (on ENST00000591111; = p.Q3790L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as COSV59914943; called by muse, mutect2, varscan2
- TYMP | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772046185, COSV52686750; called by muse, mutect2, varscan2
- TYRO3 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55481275, COSV55487658; called by muse, mutect2, varscan2
- UBAP2 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.366); catalogued as COSV62545428, COSV62548950; called by muse, mutect2, varscan2
- UNC5B | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV58974964; called by muse, mutect2, varscan2
- UQCRQ | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51525893; called by muse, mutect2, varscan2
- USP34 | c.3709C>G p.L1237V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV68398939; called by muse, mutect2, varscan2
- UVRAG | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62101812; called by muse, mutect2
- ZBBX | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV56784066; called by muse, mutect2, varscan2
- ZFHX4 | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50551279; called by muse, mutect2, varscan2
- ZFP36L2 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV56698979, COSV56699574, COSV99143900; called by muse, mutect2, varscan2
- ZNF507 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758381137, COSV61330269; called by muse, mutect2, varscan2
- ZNF597 | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV57083674, COSV57085949; called by muse, mutect2, varscan2
- AAR2 | c.431_439delinsGAG p.T144_K147delinsRE | In Frame Del (DEL) | VAF 34/156 reads (22%) | called by pindel, varscan2*
- AHNAK | c.345_357del p.S115Rfs*15 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- MFSD8 | c.1271del p.V424Gfs*2 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.4482dup p.E1495* | Frame Shift Ins (INS) | VAF 27/273 reads (10%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.1700_1704del p.S567Ffs*10 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | called by mutect2, pindel, varscan2
- ABHD11 | c.846C>T p.L282= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV56105325; called by muse, mutect2, varscan2
- ADD3 | c.639C>T p.F213= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV53320887; called by muse, mutect2, varscan2
- AP002748.5 | c.936G>C p.L312= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100567735; called by muse, mutect2
- APC2 | c.2622C>T p.L874= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99279250; called by muse, mutect2, varscan2
- ASNS | c.981C>T p.V327= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs769326809, COSV51550648; called by muse, mutect2
- ATN1 | c.930C>G p.L310= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV63110355; called by muse, mutect2, varscan2
- BCAR1 | c.2238C>T p.F746= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV50779076; called by muse, mutect2, varscan2
- CACNA1B | c.1572C>G p.L524= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53116322; called by muse, mutect2, varscan2
- CACNA1F | c.723A>T p.A241= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV59903314; called by muse, varscan2
- CACNG4 | c.981G>T p.V327= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV50924266; called by muse, mutect2, varscan2
- CCDC87 | c.2034G>A p.L678= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV59578490; called by muse, mutect2, varscan2
- CD59 | c.24C>G p.V8= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV60918993; called by muse, mutect2
- CNOT1 | c.3804G>A p.E1268= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1240474585, COSV55313819; called by muse, mutect2
- CPA3 | c.441T>C p.S147= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV56043997; called by muse, mutect2, varscan2
- CSMD1 | c.7977T>C p.H2659= (on ENST00000520002; = p.H2658= on NM_033225.6) | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as rs1420433528, COSV59289766; called by muse, mutect2, varscan2
- DNAH8 | c.2925G>T p.G975= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV59429556; called by mutect2, varscan2
- DOCK3 | c.2292C>T p.F764= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1181055200, COSV56504659; called by muse, mutect2
- DSTN | c.108C>T p.V36= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV55712305; called by muse, mutect2, varscan2
- EVI5 | c.1203C>T p.V401= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV64825788; called by muse, mutect2, varscan2
- FBXO41 | c.2490G>A p.G830= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs1185112178, COSV54582328; called by muse, mutect2, varscan2
- FXR1 | c.834C>T p.F278= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV59761409; called by muse, mutect2, varscan2
- GARS1 | c.1371G>A p.E457= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV66827960; called by muse, mutect2, varscan2
- GC | c.138C>A p.V46= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56735678, COSV99909497; called by muse, mutect2, varscan2
- GPR183 | c.969G>C p.L323= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV63117180; called by muse, mutect2, varscan2
- GRK6 | c.1458C>T p.V486= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV62681920; called by muse, mutect2, varscan2
- GTF2IRD1 | c.588C>A p.I196= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99734218, COSV99735594; called by muse, mutect2, varscan2
- HYI | c.765C>T p.F255= (on ENST00000372434 / NM_001330526.2; = p.F230= on NM_031207.6) | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV65094217; called by muse, mutect2, varscan2
- IGSF22 | c.1680G>A p.Q560= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV60031515; called by muse, mutect2, varscan2
- LNPEP | c.2277G>A p.E759= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV51476664; called by muse, mutect2, varscan2
- LRP1 | c.3468C>T p.T1156= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs1347019663, COSV54503612; called by muse, mutect2, varscan2
- MAST3 | c.2781G>T p.S927= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV53218022; called by muse, varscan2
- MED12 | c.4134C>G p.L1378= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV61333791; called by muse, mutect2, varscan2
- MED12 | c.4293C>A p.L1431= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV61333804; called by muse, mutect2, varscan2
- MOCS3 | c.600C>T p.L200= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV54865742; called by muse, varscan2
- MYCBP2 | c.4287G>C p.L1429= (on ENST00000357337; = p.L1467= on NM_015057.5) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs377177103, COSV62011678; called by muse, mutect2, varscan2
- OR1C1 | c.867C>A p.I289= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV68715457; called by muse, mutect2, varscan2
- PCLO | c.2988G>A p.V996= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV61619415; called by muse, mutect2, varscan2
- PCMTD2 | c.564C>T p.V188= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV55059281; called by muse, mutect2, varscan2
- PDPR | c.2310C>T p.F770= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV55349631; called by muse, mutect2, varscan2
- PHOX2B | c.471G>A p.E157= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99890932; called by muse, mutect2
- PIDD1 | c.2013C>T p.A671= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1298388062, COSV57192425; called by muse, mutect2, varscan2
- PKHD1 | c.5166C>T p.I1722= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV61863471; called by muse, mutect2
- PNPLA7 | c.150C>T p.F50= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1052637819, COSV52995085; called by muse, mutect2, varscan2
- POT1 | c.375C>T p.F125= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV62928375; called by muse, mutect2, varscan2
- PSD3 | c.2758C>T p.L920= (on ENST00000440756; = p.L919= on NM_015310.4) | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs377209838, COSV54067396; called by muse, mutect2, varscan2
- PTBP3 | c.567C>G p.L189= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV52956154; called by muse, mutect2, varscan2
- RHBDF2 | c.894A>G p.E298= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV100489249; called by muse, mutect2
- SLC35B2 | c.1221C>G p.L407= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV51487931; called by muse, mutect2, varscan2
- SLC38A11 | c.951C>A p.L317= (on ENST00000409149 / NM_001351539.1; = p.L295= on NM_173512.2) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV58052069; called by muse, mutect2, varscan2
- SZT2 | c.3717C>T p.V1239= (on ENST00000634258 / NM_001365999.1; = p.V1182= on NM_015284.4) | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV65167756; called by muse, mutect2, varscan2
- TENM1 | c.708C>A p.T236= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as COSV64426331; called by muse, mutect2, varscan2
- TRRAP | c.723G>A p.L241= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV62840348, COSV62848788; called by muse, mutect2, varscan2
- ULBP3 | c.684C>G p.L228= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV66253992; called by muse, mutect2, varscan2
- UTRN | c.8820C>G p.L2940= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV62307722; called by muse, mutect2, varscan2
- ZFHX3 | c.10881G>A p.A3627= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs892312481, COSV51710753; called by muse, mutect2, varscan2
- ZFPM2 | c.969G>A p.V323= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV65872748; called by muse, mutect2, varscan2
- OR2W5 | n.1042C>A | RNA (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- SNORD115-3 | n.1G>A | RNA (SNP) | VAF 77/334 reads (23%) | catalogued as rs761103960; called by muse, mutect2, varscan2
